Somatic mutation profile of tumor specimen TCGA-CG-4306-01A (aliquot TCGA-CG-4306-01A-01D-1158-08) from TCGA case TCGA-CG-4306, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-CG-4306-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5916e5ea-79f4-4d92-99e0-5beefd572b17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4306-10A (Blood Derived Normal), aliquot TCGA-CG-4306-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55ae9488-13d2-48c8-a382-e34af7e85991

The open-access MAF lists 1,312 somatic variants for this specimen: 1,010 protein-altering or splice-affecting, 277 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 630, Silent 277, Frame Shift Del 247, Frame Shift Ins 60, Nonsense Mutation 44, Splice Site 16, Intron 8, In Frame Del 7, 3'UTR 6, Splice Region 6, RNA 4, 5'UTR 3.

Variants (750 of 1,312; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3774dup p.W1259Lfs*19 | Frame Shift Ins (INS) | VAF 16/98 reads (16%) | catalogued as rs72664220; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ALOX12B | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs750066836, CM162707, COSV59872355; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 32/147 reads (22%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BARD1 | c.623dup p.K209Efs*5 | Frame Shift Ins (INS) | VAF 23/133 reads (17%) | catalogued as rs587780033; ClinVar: pathogenic; called by mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 34/140 reads (24%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- COL1A2 | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs66612022, CM011298, CM950287, COSV51956747; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTSF | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397514733, CM132040, COSV59748384; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GAA | c.2242del p.E748Rfs*16 | Frame Shift Del (DEL) | VAF 26/144 reads (18%) | catalogued as rs777275355, CM082763, CM128388, CM970554; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 23/112 reads (21%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH2 | c.687del p.A230Lfs*16 | Frame Shift Del (DEL) | VAF 15/86 reads (17%) | catalogued as rs63749897; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 110/274 reads (40%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYH7 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397516101, CM003684, CM003685, COSV62516636; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PAFAH1B1 | c.910del p.S304Vfs*29 | Frame Shift Del (DEL) | VAF 34/157 reads (22%) | catalogued as rs587784292; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCCB | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 47/224 reads (21%) | catalogued as rs749908889, CM983750, COSV52444734; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PXDN | c.2568del p.C857Afs*5 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs558163499, CD117085; ClinVar: pathogenic; called by mutect2, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 46/162 reads (28%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- SCN1A | c.4554dup p.P1519Tfs*18 (on ENST00000303395 / NM_001202435.3; = p.P1508Tfs*18 on NM_006920.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 28/128 reads (22%) | catalogued as rs794726825; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC16A1 | c.41del p.P14Qfs*10 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA12 | c.5448G>A p.M1816I (on ENST00000272895 / NM_173076.3; = p.M1498I on NM_015657.3) | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs757551848, COSV55956453; called by muse, mutect2, varscan2
- ABCA7 | c.2298T>A p.N766K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.339); catalogued as COSV54028013; called by muse, mutect2, varscan2
- ABCA9 | c.4075G>A p.E1359K | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV60623808; called by muse, mutect2, varscan2
- ABCB6 | c.953del p.G318Vfs*9 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | catalogued as rs777439793; called by mutect2, pindel, varscan2
- ABCB8 | c.1006G>A p.E336K (on ENST00000297504 / NM_001282291.2; = p.E319K on NM_007188.5) | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750804178, COSV52503932; called by muse, mutect2
- ABCC12 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs535991858, COSV60911226; called by muse, mutect2, varscan2
- ABCG2 | c.1253del p.N418Mfs*16 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | catalogued as COSV52950407; called by mutect2, pindel, varscan2
- ABLIM2 | c.354del p.D120Tfs*3 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | catalogued as rs749606695; called by mutect2, pindel, varscan2
- AC013489.1 | c.407A>G p.N136S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs375831122; called by muse, mutect2, varscan2
- AC092143.1 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); catalogued as COSV59247382; called by muse, mutect2, varscan2
- AC131160.1 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs775278881, COSV59414341; called by muse, mutect2, varscan2
- ACAD10 | c.1936C>T p.H646Y | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV58155893; called by muse, mutect2, varscan2
- ACD | c.803A>G p.Q268R (on ENST00000620338; = p.Q179R on NM_022914.3) | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV54667084; called by muse, mutect2, varscan2
- ACSL6 | c.1388G>A p.C463Y (on ENST00000379240; = p.C488Y on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57297347; called by muse, mutect2, varscan2
- ACSL6 | c.31C>T p.R11* (on ENST00000379240; = p.R36* on NM_015256.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as rs767774674, COSV57295759; called by muse, mutect2, varscan2
- ACTG2 | c.887C>G p.A296G | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV61828160; called by muse, mutect2, varscan2
- ACTRT1 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 88/184 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV64419236; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 106/244 reads (43%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVR2B | c.1460G>A p.G487D | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.045); catalogued as COSV61702078; called by muse, mutect2
- ADAM11 | c.104del p.G35Afs*52 | Frame Shift Del (DEL) | VAF 29/135 reads (21%) | catalogued as rs767694891; called by mutect2, pindel, varscan2
- ADAM30 | c.1865dup p.N622Kfs*5 | Frame Shift Ins (INS) | VAF 38/162 reads (23%) | catalogued as rs750058585; called by mutect2, varscan2
- ADAMTS14 | c.2695C>T p.R899W | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199771530, COSV64601484; called by muse, varscan2
- ADARB2 | c.1513+1G>A p.X505_splice | Splice Site (SNP) | VAF 67/247 reads (27%) | catalogued as rs778321753, COSV67221201; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745856523, COSV58443114; called by muse, mutect2, varscan2
- ADD2 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 92/355 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs201022450; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 32/170 reads (19%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRL3 | c.2161G>A p.A721T (on ENST00000506720 / NM_001322402.2; = p.A653T on NM_015236.6) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.403); catalogued as COSV72230332; called by muse, mutect2, varscan2
- AFF4 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs756072790, COSV54793809; called by muse, mutect2, varscan2
- AGL | c.2765G>A p.C922Y | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV54051799; called by muse, mutect2, varscan2
- AGO1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs774432228, COSV64595117; called by muse, mutect2, varscan2
- AGO3 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs754906872, COSV55791941; called by muse, mutect2, varscan2
- AGO4 | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64617000; called by muse, mutect2, varscan2
- AGRN | c.5969C>T p.A1990V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.675); catalogued as COSV65069109; called by muse, mutect2
- AHNAK | c.17291C>T p.P5764L | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs778779045, COSV57211426; called by muse, mutect2, varscan2
- AIFM3 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs201100852; called by muse, mutect2, varscan2
- AJM1 | c.2239C>T p.R747C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778041533, COSV56032636; called by muse, mutect2, varscan2
- AK8 | c.36del p.E13Rfs*14 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | catalogued as rs757477831; called by mutect2, pindel, varscan2
- AK9 | c.5708_5709dup p.R1904Sfs*4 | Frame Shift Ins (INS) | VAF 86/390 reads (22%) | catalogued as rs1325930894; called by mutect2, varscan2
- AKR1C3 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 42/156 reads (27%) | catalogued as COSV65910335; called by muse, mutect2, varscan2
- ALAS2 | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1569547781, CM095124, CM109572, COSV58189881; called by muse, mutect2, varscan2
- ALDH1L1 | c.295del p.R99Gfs*62 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs755422577, COSV99856805; called by mutect2, pindel
- ALDH1L2 | c.340A>G p.M114V | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.649); catalogued as rs201722201, COSV51555167; called by muse, mutect2, varscan2
- ALDH2 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs1357957696, COSV55669971; called by muse, mutect2, varscan2
- ALDH3A1 | c.1334del p.P445Rfs*6 | Frame Shift Del (DEL) | VAF 43/162 reads (27%) | catalogued as rs778623472, COSV56735668; called by mutect2, pindel, varscan2
- ALOX12B | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 110/408 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV59872349; called by muse, mutect2, varscan2
- AMER3 | c.2320C>T p.P774S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV58466253; called by muse, mutect2
- AMPD1 | c.1838C>T p.T613I | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV62415783; called by muse, mutect2, varscan2
- ANK3 | c.8713C>T p.R2905C | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs757636476, COSV55046882; called by muse, mutect2, varscan2
- ANO1 | c.1939C>T p.R647* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV60283632; called by muse, mutect2, varscan2
- ANTXR1 | c.295A>G p.R99G | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1222198631, COSV58012689; called by muse, mutect2, varscan2
- AOC1 | c.2222del p.P741Lfs*54 | Frame Shift Del (DEL) | VAF 20/101 reads (20%) | catalogued as rs999461756; called by mutect2, pindel, varscan2
- AP1G2 | c.127del p.D43Tfs*30 | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | catalogued as COSV58111047; called by mutect2, pindel, varscan2
- AP5Z1 | c.1625C>A p.P542H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV62241420; called by muse, mutect2, varscan2
- APC | c.3859A>C p.I1287L | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57339375, COSV57345224; called by muse, mutect2, varscan2
- APOA4 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 33/141 reads (23%) | catalogued as rs772319887, COSV100759322; called by muse, mutect2, varscan2
- APOB | c.11410G>A p.E3804K | Missense Mutation (SNP) | VAF 89/381 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.557); catalogued as COSV51932620; called by muse, varscan2
- APOB | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as rs780841518, COSV51922701; called by muse, mutect2, varscan2
- APOE | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as rs749102800, COSV99376105; called by muse, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 27/228 reads (12%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARHGAP26 | c.590T>G p.V197G | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50828079; called by muse, mutect2, varscan2
- ARHGAP27 | c.1846G>A p.A616T (on ENST00000428638 / NM_001282290.1; = p.A275T on NM_199282.3) | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs147050844; called by muse, mutect2, varscan2
- ARHGEF12 | c.3940C>T p.P1314S | Missense Mutation (SNP) | VAF 77/337 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV63104053; called by muse, mutect2, varscan2
- ARL13B | c.679C>T p.R227* (on ENST00000394222 / NM_001174150.2; = p.R120* on NM_144996.4) | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as rs765368269, COSV57397766; called by muse, mutect2, varscan2
- ARL14EP | c.266dup p.N89Kfs*6 | Frame Shift Ins (INS) | VAF 48/216 reads (22%) | catalogued as rs1247324796; called by mutect2, varscan2
- ARMC10 | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.136); catalogued as rs142543653; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs753865255; called by mutect2, varscan2
- ARX | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866153168, COSV66875050, COSV66875669; called by muse, mutect2, varscan2
- ASB5 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 50/256 reads (20%) | catalogued as rs370097719; called by muse, mutect2, varscan2
- ASH1L | c.3388C>T p.P1130S | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.341); catalogued as COSV64207359; called by muse, mutect2, varscan2
- ASL | c.1298G>T p.S433I | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59188341; called by muse, mutect2, varscan2
- ASPN | c.201del p.P68Hfs*24 | Frame Shift Del (DEL) | VAF 21/90 reads (23%) | catalogued as rs778526424; called by mutect2, pindel, varscan2
- ASXL3 | c.3276G>T p.E1092D | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV52463832; called by muse, mutect2, varscan2
- ATP10A | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755196001, COSV63516408; called by muse, mutect2, varscan2
- ATP12A | c.997C>A p.L333M | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV54515082; called by muse, mutect2, varscan2
- ATP12A | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54512555; called by muse, mutect2, varscan2
- ATP2C1 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 58/296 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs774028528, COSV60755506; called by muse, mutect2, varscan2
- ATP5MG | c.305A>G p.D102G | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as rs1555132628, COSV56138943; called by muse, varscan2
- ATP9B | c.1657A>G p.N553D | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56949900; called by muse, mutect2, varscan2
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 44/191 reads (23%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- AUP1 | c.572A>G p.Q191R | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV51207093; called by muse, mutect2, varscan2
- B3GNT7 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs757654927, COSV55006274; called by muse, mutect2, varscan2
- B3GNT8 | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as COSV54196708; called by muse, mutect2, varscan2
- B3GNT9 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.94); catalogued as COSV54626921; called by muse, mutect2, varscan2
- B4GALT2 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753886330, COSV52543251; called by muse, mutect2, varscan2
- BACE1 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.952); catalogued as COSV57284575; called by muse, mutect2, varscan2
- BACH1 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs756562023, COSV54518496; called by muse, mutect2, varscan2
- BAZ2A | c.5365C>T p.R1789* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as rs767230458, COSV51633367; called by muse, mutect2
- BIRC6 | c.13960C>T p.R4654* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as COSV70198391; called by muse, mutect2, varscan2
- BOD1L1 | c.2806G>A p.A936T | Missense Mutation (SNP) | VAF 82/320 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV50010229; called by muse, mutect2, varscan2
- BRAP | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 92/327 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.07); catalogued as rs1234250530, COSV58155880; called by muse, mutect2, varscan2
- BRCA1 | c.3082C>T p.R1028C | Missense Mutation (SNP) | VAF 61/316 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.276); catalogued as rs80357049, COSV58788564; ClinVar: conflicting interpretations of pathogenicity / benign / likely benign; called by muse, mutect2, varscan2
- BRD1 | c.1939G>A p.V647M | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.316); catalogued as rs751309590, COSV53456222; called by muse, mutect2, varscan2
- BRD3 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.035); catalogued as rs759360626, COSV57703134; called by muse, mutect2, varscan2
- BRI3BP | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1337179002, COSV58295927; called by muse, mutect2, varscan2
- BSX | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1565347536, COSV58005447; called by muse, mutect2, varscan2
- BTBD1 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV99915481; called by muse, mutect2
- C12orf65 | c.477G>T p.W159C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.319); catalogued as COSV53516123; called by muse, mutect2, varscan2
- C14orf93 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs898194929, COSV54440835; called by muse, mutect2
- C19orf18 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV58705740; called by muse, mutect2, varscan2
- C1QL1 | c.656G>A p.S219N | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53646955; called by muse, mutect2, varscan2
- C1orf94 | c.679C>T p.R227C (on ENST00000488417 / NM_001134734.2; = p.R37C on NM_032884.5) | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as rs1472847493, COSV64913805; called by muse, mutect2, varscan2
- CACNA1B | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53123004; called by muse, mutect2, varscan2
- CACNB4 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs765848806, COSV52392653; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACUL1 | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs1308235959, COSV60993898; called by muse, mutect2, varscan2
- CALCA | c.203A>T p.Q68L | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV59027770; called by muse, mutect2, varscan2
- CALD1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775853439, COSV62647217; called by muse, mutect2, varscan2
- CAMTA1 | c.2432G>A p.R811Q | Missense Mutation (SNP) | VAF 104/357 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.978); catalogued as rs947417680, COSV57896227, COSV57925053; called by muse, mutect2, varscan2
- CAPS2 | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60825051; called by muse, mutect2
- CARD11 | c.2899C>T p.R967C | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as rs149857605; called by muse, mutect2, varscan2
- CARMIL3 | c.273G>T p.M91I | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV57726054; called by muse, mutect2, varscan2
- CASP8 | c.1181C>T p.P394L (on ENST00000432109 / NM_033355.3; = p.P411L on NM_001228.4) | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51846287, COSV51861191; called by muse, mutect2, varscan2
- CASS4 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 53/294 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756414497, COSV64385994; called by muse, mutect2, varscan2
- CBX5 | c.317del p.K106Rfs*31 | Frame Shift Del (DEL) | VAF 101/414 reads (24%) | catalogued as rs780649799; called by mutect2, varscan2
- CBX8 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 60/350 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1304573522, COSV53936240; called by muse, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 36/158 reads (23%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC62 | c.1566A>G p.I522M | Missense Mutation (SNP) | VAF 87/338 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV53432703; called by muse, mutect2, varscan2
- CCDC70 | c.371T>G p.F124C | Missense Mutation (SNP) | VAF 80/469 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV54430056; called by muse, mutect2, varscan2
- CCDC8 | c.967G>C p.A323P | Missense Mutation (SNP) | VAF 74/341 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV56773033; called by muse, mutect2, varscan2
- CCDC88A | c.2032dup p.T678Nfs*4 | Frame Shift Ins (INS) | VAF 18/60 reads (30%) | catalogued as rs750732366; called by mutect2, varscan2
- CCDC96 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 65/276 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.142); catalogued as COSV59508540; called by muse, mutect2, varscan2
- CCNF | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 88/331 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs773326682, COSV53538257; called by muse, mutect2, varscan2
- CD209 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 152/355 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.759); catalogued as rs1013332025, COSV52652464; called by muse, varscan2
- CD81 | c.194T>G p.L65R | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55132772; called by muse, mutect2, varscan2
- CDAN1 | c.587G>T p.R196M | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51159700; called by muse, mutect2, varscan2
- CDC40 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 11/88 reads (13%) | catalogued as COSV57009115; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 62/242 reads (26%) | catalogued as rs762194001; called by mutect2, varscan2
- CDC73 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 75/308 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV66465313; called by muse, mutect2, varscan2
- CDH11 | c.1460A>T p.K487M | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as COSV51759327, COSV51759358, COSV51764779; called by muse, mutect2, varscan2
- CDH16 | c.677C>T p.T226I | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV55336280; called by muse, mutect2, varscan2
- CDH20 | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1166858914, COSV53008554, COSV53018843, COSV53020216; called by muse, mutect2, varscan2
- CDK5 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs369223059, COSV52520884; called by muse, mutect2, varscan2
- CDK5R2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV56936009; called by muse, mutect2, varscan2
- CDYL2 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs1375093823, COSV73647628, COSV73647672; called by muse, mutect2, varscan2
- CEACAM1 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.404); catalogued as rs138618516; called by muse, mutect2, varscan2
- CEBPZ | c.2885-3del | Splice Region (DEL) | VAF 22/100 reads (22%) | catalogued as rs375852685; called by mutect2, varscan2
- CELF2 | c.1223A>C p.Q408P (on ENST00000416382 / NM_001025077.3; = p.Q421P on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.087); catalogued as COSV59972873; called by muse, mutect2
- CELSR1 | c.5786C>T p.P1929L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs374468252; called by muse, mutect2, varscan2
- CELSR3 | c.4988+2T>C p.X1663_splice | Splice Site (SNP) | VAF 22/80 reads (28%) | catalogued as COSV50850245; called by muse, varscan2
- CENPJ | c.2810C>T p.A937V | Missense Mutation (SNP) | VAF 68/322 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV67883331; called by muse, mutect2, varscan2
- CEP126 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 65/347 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV54824353; called by muse, mutect2, varscan2
- CEP57 | c.785del p.K262Rfs*31 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs762013265, COSV57689966; called by mutect2, varscan2
- CERCAM | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs780903439, COSV65710808; called by muse, mutect2, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 24/83 reads (29%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP53 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 129/467 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753096348, COSV68351828; called by muse, mutect2, varscan2
- CFAP74 | c.1146del p.T383Pfs*7 | Frame Shift Del (DEL) | VAF 40/214 reads (19%) | catalogued as rs771497538; called by mutect2, pindel, varscan2
- CFH | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV62777166; called by muse, mutect2
- CGN | c.3227G>A p.R1076Q | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372439240; called by muse, mutect2, varscan2
- CHD1L | c.2021T>C p.M674T | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV63613664; called by muse, mutect2, varscan2
- CHD9 | c.7898G>A p.R2633Q (on ENST00000398510 / NM_001382353.1; = p.R2617Q on NM_025134.7) | Missense Mutation (SNP) | VAF 58/271 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs370913156; called by muse, mutect2, varscan2
- CHEK1 | c.676del p.T226Hfs*14 | Frame Shift Del (DEL) | VAF 38/165 reads (23%) | catalogued as rs757716680, COSV54024545; called by mutect2, varscan2
- CHERP | c.809del p.N270Tfs*385 | Frame Shift Del (DEL) | VAF 40/200 reads (20%) | catalogued as COSV52228072; called by mutect2, pindel, varscan2
- CHPF | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs779983221, COSV60534497; called by muse, mutect2, varscan2
- CHPF2 | c.1941del p.S648Pfs*13 | Frame Shift Del (DEL) | VAF 13/77 reads (17%) | catalogued as rs746469175; called by mutect2, pindel, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 19/116 reads (16%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRM4 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs759941649, COSV63126375; called by muse, mutect2, varscan2
- CHST15 | c.23G>A p.C8Y | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as COSV60561629; called by muse, mutect2, varscan2
- CHST2 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.995); catalogued as rs145959139; called by muse, varscan2
- CHSY3 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1445082364, COSV59276339; called by muse, mutect2, varscan2
- CIT | c.5783C>T p.T1928M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as rs1351510584, COSV55866631, COSV55881213; called by muse, mutect2, varscan2
- CKAP4 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1459200044, COSV65172093; called by muse, mutect2, varscan2
- CLASRP | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1162453903, COSV55515808; called by muse, mutect2, varscan2
- CLK2 | c.583A>G p.I195V (on ENST00000368361 / NM_001294339.2; = p.I194V on NM_003993.4) | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.727); catalogued as COSV62877005; called by muse, mutect2
- CLRN3 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1267051610, COSV64098101; called by muse, mutect2, varscan2
- CNBD2 | c.1473G>T p.Q491H (on ENST00000373973 / NM_001365709.1; = p.Q487H on NM_080834.4) | Missense Mutation (SNP) | VAF 16/293 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV100839099; called by muse, mutect2
- CNOT1 | c.2706del p.Q904Sfs*9 | Frame Shift Del (DEL) | VAF 50/305 reads (16%) | catalogued as rs1397135931, COSV55313852; called by mutect2, pindel, varscan2
- CNOT11 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56819460; called by muse, varscan2
- CNPY1 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs868523229, COSV58787201; called by muse, mutect2, varscan2
- CNPY4 | c.41del p.L14Wfs*11 | Frame Shift Del (DEL) | VAF 31/140 reads (22%) | catalogued as rs1347948509; called by mutect2, pindel, varscan2
- CNTN4 | c.2299G>A p.V767M | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs200039799, COSV61867169; called by muse, mutect2, varscan2
- CNTN6 | c.2389T>C p.S797P | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1312181987, COSV63169637; called by muse, mutect2
- CNTNAP1 | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 100/432 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.581); catalogued as COSV52849585; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | catalogued as rs374805044; called by mutect2, varscan2
- COG4 | c.2363G>A p.R788H | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs142971847; called by muse, mutect2, varscan2
- COL12A1 | c.6080G>A p.G2027E | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780058273, COSV59394345; called by muse, mutect2, varscan2
- COL16A1 | c.2719-2A>G p.X907_splice | Splice Site (SNP) | VAF 65/293 reads (22%) | catalogued as COSV54704306; called by muse, mutect2, varscan2
- COL4A2 | c.260A>G p.K87R | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64627424; called by muse, mutect2, varscan2
- COL4A6 | c.4718C>T p.A1573V | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV57864116; called by muse, mutect2, varscan2
- COL5A3 | c.4782+1G>A p.X1594_splice | Splice Site (SNP) | VAF 8/88 reads (9%) | catalogued as rs1300392737, COSV53409621; called by muse, mutect2, varscan2
- COL6A3 | c.9245del p.P3082Hfs*16 | Frame Shift Del (DEL) | VAF 30/111 reads (27%) | catalogued as CM155239; called by mutect2, pindel, varscan2
- COL7A1 | c.4127del p.P1376Lfs*23 | Frame Shift Del (DEL) | VAF 24/124 reads (19%) | catalogued as rs757976973; called by mutect2, pindel
- COL9A2 | c.2011G>A p.G671R | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV101028524; called by muse, mutect2, varscan2
- COPB2 | c.2521G>T p.D841Y | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV60349547, COSV60349674; called by muse, mutect2, varscan2
- CPLX4 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs752019452, COSV55313481; called by muse, mutect2, varscan2
- CPVL | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs750931528, COSV55300420; called by muse, mutect2, varscan2
- CPXM2 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1406441755, COSV53860513; called by muse, mutect2, varscan2
- CR1L | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 44/181 reads (24%) | catalogued as rs372948821, COSV99687713; called by muse, mutect2, varscan2
- CROCC | c.3604C>T p.R1202* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV65011597; called by muse, mutect2, varscan2
- CRTAP | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as rs572086683, COSV100310028, COSV58013744; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD2 | c.7417G>A p.A2473T | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs890359904, COSV99589996; called by muse, mutect2, varscan2
- CSRNP2 | c.993G>T p.E331D | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.879); catalogued as COSV50397163; called by muse, varscan2
- CTCFL | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753318139, COSV54772895; called by muse, mutect2, varscan2
- CTNND2 | c.2705G>A p.R902Q | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs748058547, COSV58882987, COSV58884485; called by muse, mutect2, varscan2
- CUBN | c.5177G>A p.G1726D | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64714062; called by muse, mutect2, varscan2
- CUL7 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs754739961, COSV54815813; called by muse, mutect2, varscan2
- CUX2 | c.3416G>A p.S1139N | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs1044051285, COSV55630022; called by muse, mutect2, varscan2
- CXXC5 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.697); catalogued as rs1314626635, COSV56793660; called by muse, mutect2, varscan2
- CYFIP2 | c.1570C>T p.R524* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | catalogued as COSV59033939; called by muse, mutect2, varscan2
- DAGLB | c.481A>G p.K161E | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV51702308, COSV51707091; called by muse, mutect2, varscan2
- DCAF1 | c.1732T>C p.Y578H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.735); catalogued as COSV60042360; called by muse, mutect2
- DCDC1 | c.2494C>A p.H832N | Missense Mutation (SNP) | VAF 62/260 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.283); catalogued as COSV100663426; called by muse, mutect2, varscan2
- DCLK3 | c.327del p.R110Gfs*69 | Frame Shift Del (DEL) | VAF 36/223 reads (16%) | catalogued as COSV101373865, COSV69362732; called by mutect2, pindel, varscan2
- DCTN3 | c.232A>G p.I78V | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52407094; called by muse, mutect2, varscan2
- DDX23 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 131/531 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1462751560, COSV57282974; called by muse, mutect2, varscan2
- DDX55 | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772257167, COSV53015060, COSV53015905; called by muse, mutect2, varscan2
- DEDD2 | c.458del p.P153Qfs*42 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | catalogued as rs758890887, COSV60141885; called by mutect2, pindel, varscan2
- DEFB118 | c.78del p.K26Nfs*19 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | catalogued as rs750510475, COSV53620107; called by mutect2, varscan2
- DENND2A | c.1156A>G p.I386V | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs752648671, COSV52050465; called by muse, mutect2, varscan2
- DHX15 | c.1493C>T p.T498I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV61026655; called by muse, mutect2, varscan2
- DISP1 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.121); catalogued as rs765609888, COSV52657862; called by muse, mutect2, varscan2
- DLG2 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs749744948, COSV54638303; called by muse, mutect2, varscan2
- DLG4 | c.1952G>A p.R651H (on ENST00000399506 / NM_001321075.3; = p.R694H on NM_001365.4) | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs750438640, COSV57237888; called by muse, mutect2, varscan2
- DLL3 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs141671275; called by muse, varscan2
- DNAH1 | c.9506G>A p.R3169H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1415017697, COSV70228337; called by muse, mutect2
- DNAH17 | c.4481G>A p.R1494Q | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs760905784, COSV67750388; called by muse, mutect2, varscan2
- DNAH5 | c.11501G>A p.R3834H | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs139914691; called by muse, mutect2, varscan2
- DNAJA1 | c.1127A>G p.Y376C | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV58310212; called by muse, mutect2
- DNMBP | c.4220C>A p.S1407Y | Missense Mutation (SNP) | VAF 70/352 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as COSV60624070; called by muse, mutect2
- DNMT3A | c.1992G>T p.E664D | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53048725; called by muse, mutect2, varscan2
- DOCK10 | c.1372del p.A458Lfs*31 | Frame Shift Del (DEL) | VAF 74/327 reads (23%) | catalogued as rs776490300; called by mutect2, pindel, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 34/95 reads (36%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DPY19L4 | c.1847A>G p.N616S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.315); catalogued as COSV68962718; called by muse, mutect2, varscan2
- DRC7 | c.1949C>T p.T650M | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.333); catalogued as rs759718926, COSV61054267; called by muse, mutect2, varscan2
- DSC3 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as rs145242863; called by muse, mutect2, varscan2
- DSCAML1 | c.1735G>A p.G579R (on ENST00000321322; = p.G519R on NM_020693.4) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58386269, COSV58388840; called by muse, mutect2, varscan2
- DSCAML1 | c.329C>T p.A110V (on ENST00000321322; = p.A50V on NM_020693.4) | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.439); catalogued as rs747042222, COSV58386615; called by muse, mutect2
- DSP | c.6536del p.K2179Rfs*8 | Frame Shift Del (DEL) | VAF 17/134 reads (13%) | catalogued as COSV65791456; called by mutect2, pindel, varscan2
- DUOXA2 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1280998645, COSV50993366; called by muse, mutect2
- DUS2 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs1298030671, COSV62708284; called by muse, mutect2, varscan2
- DVL2 | c.1076C>A p.P359H | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50035482; called by muse, mutect2, varscan2
- DVL2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as rs780268199, COSV50034912; called by muse, mutect2, varscan2
- DYSF | c.1097G>A p.S366N | Missense Mutation (SNP) | VAF 106/481 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV50301205; called by muse, mutect2, varscan2
- EDF1 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750972709, COSV56375457; called by muse, mutect2, varscan2
- EGR1 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 72/296 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53518935; called by muse, mutect2, varscan2
- EGR2 | c.1180G>A p.G394S | Missense Mutation (SNP) | VAF 61/319 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1272471096, COSV54346659; called by muse, mutect2, varscan2
- EIF2B4 | c.1216C>T p.H406Y (on ENST00000347454 / NM_001034116.2; = p.H405Y on NM_015636.3) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV61456887; called by muse, mutect2, varscan2
- ELAVL3 | c.47del p.G16Afs*35 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as rs751148694; called by mutect2, varscan2
- EN1 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54630875; called by muse, mutect2, varscan2
- EOMES | c.1716G>T p.M572I | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.107); catalogued as COSV55412195; called by muse, mutect2, varscan2
- EPG5 | c.6584C>T p.A2195V | Missense Mutation (SNP) | VAF 96/429 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs764699240, COSV56348446; called by muse, mutect2, varscan2
- EPHA5 | c.1862G>A p.C621Y | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.825); catalogued as COSV56641209, COSV56648770; called by muse, mutect2, varscan2
- EPHA6 | c.2499del p.R834Gfs*8 (on ENST00000389672 / NM_001080448.3; = p.R226Gfs*8 on NM_173655.4) | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | catalogued as rs765418329; called by mutect2, pindel, varscan2
- EPPK1 | c.1717C>A p.L573M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV73261086; called by muse, mutect2, varscan2
- ERCC2 | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.318); catalogued as COSV55540295, COSV55544079; called by muse, mutect2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs780487406; called by mutect2, varscan2
- ERP44 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 16/212 reads (8%) | catalogued as rs374215522; called by muse, mutect2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 28/112 reads (25%) | catalogued as rs775950025; called by mutect2, varscan2
- F13B | c.1001T>C p.V334A | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV66373518; called by muse, mutect2, varscan2
- FAHD2B | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.794); catalogued as COSV55630467; called by muse, mutect2, varscan2
- FAM135A | c.142T>A p.L48M | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52050379; called by muse, mutect2, varscan2
- FAM151A | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as rs751838721, COSV56363771; called by muse, mutect2, varscan2
- FAM227B | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 80/376 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.222); catalogued as COSV54809773; called by muse, mutect2, varscan2
- FAM83B | c.1837A>G p.T613A | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV60921473; called by muse, mutect2, varscan2
- FAT1 | c.10209T>A p.I3403= | Splice Region (SNP) | VAF 12/72 reads (17%) | catalogued as COSV71673467; called by muse, mutect2, varscan2
- FAT2 | c.1859C>T p.S620F | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); catalogued as COSV55818247; called by muse, mutect2, varscan2
- FBLN2 | c.3314G>A p.R1105H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369694803; called by muse, mutect2, varscan2
- FBN1 | c.2980G>A p.E994K | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as rs780301913, CM980726, COSV57314812; called by muse, mutect2, varscan2
- FBXL18 | c.717del p.G240Afs*63 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | catalogued as COSV101212016; called by mutect2, pindel, varscan2
- FBXO10 | c.368G>A p.S123N | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.198); catalogued as COSV52832578; called by muse, mutect2, varscan2
- FBXO25 | c.1031G>A p.C344Y (on ENST00000382824 / NM_183421.2; = p.C268Y on NM_012173.3) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV52336656; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 74/200 reads (37%) | catalogued as rs748969702; called by mutect2, varscan2
- FFAR1 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.273); catalogued as rs773272438, COSV50051782; called by muse, mutect2, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 46/174 reads (26%) | catalogued as rs144178676; called by mutect2, varscan2
- FGFR4 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52810145; called by muse, mutect2, varscan2
- FGR | c.329+1G>A p.X110_splice | Splice Site (SNP) | VAF 14/71 reads (20%) | catalogued as rs755187930, COSV64969450; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 17/95 reads (18%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FIZ1 | c.748C>T p.H250Y | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV55607599; called by muse, mutect2, varscan2
- FLG | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 155/680 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV64240661; called by muse, mutect2, varscan2
- FLNA | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as rs782425251, COSV61040280; called by muse, mutect2, varscan2
- FLRT2 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.638); catalogued as rs201981148, COSV58140190; called by muse, mutect2, varscan2
- FNBP1 | c.983del p.N328Ifs*7 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs771301424; called by mutect2, varscan2
- FNIP2 | c.671T>A p.V224D | Missense Mutation (SNP) | VAF 96/426 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52439057; called by muse, mutect2, varscan2
- FOXC2 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as rs1276920391, COSV57444123; called by muse, mutect2
- FOXL2 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.116); catalogued as COSV57726683, COSV57731709; called by muse, mutect2, varscan2
- FOXQ1 | c.467del p.F156Sfs*247 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | catalogued as rs1259007659, COSV57259274; called by mutect2, pindel, varscan2
- FUBP1 | c.1270A>G p.M424V | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53929735; called by muse, mutect2, varscan2
- FYN | c.1451G>T p.R484M | Missense Mutation (SNP) | VAF 67/257 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57613278; called by muse, mutect2, varscan2
- FZD2 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.892); catalogued as rs751478883, COSV59528328; called by muse, mutect2, varscan2
- FZD8 | c.1338G>A p.W446* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV65967779; called by muse, mutect2, varscan2
- GABBR1 | c.208del p.E70Sfs*36 | Frame Shift Del (DEL) | VAF 65/274 reads (24%) | catalogued as rs1231267820; called by mutect2, pindel, varscan2
- GABPB1 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.086); catalogued as rs986519244, COSV55014615; called by muse, mutect2, varscan2
- GALNT17 | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs972749747, COSV61158751; called by muse, mutect2, varscan2
- GALNTL6 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV72552951; called by muse, mutect2, varscan2
- GASK1B | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.172); catalogued as COSV56706533; called by muse, mutect2, varscan2
- GATM | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751757258, COSV67540297; called by muse, mutect2, varscan2
- GBP6 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs141648455; called by muse, mutect2, varscan2
- GCC1 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.232); catalogued as COSV50000863; called by muse, mutect2, varscan2
- GCN1 | c.4036G>A p.A1346T | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.009); catalogued as rs753160265, COSV56105129; called by muse, mutect2, varscan2
- GDF2 | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs782719698; called by muse, mutect2, varscan2
- GDF5 | c.847G>A p.V283M | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs895865861, CM164743, COSV65500876; called by muse, mutect2, varscan2
- GFOD1 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as rs556070235, COSV64955115; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs763147690; called by mutect2, varscan2
- GJA8 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.606); catalogued as rs1272922415, COSV53788653; called by muse, mutect2, varscan2
- GLB1L2 | c.284+1G>A p.X95_splice | Splice Site (SNP) | VAF 32/102 reads (31%) | catalogued as rs750611640, COSV60278311; called by muse, mutect2, varscan2
- GLP2R | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575133662, COSV52324255; called by muse, mutect2, varscan2
- GLT1D1 | c.325T>G p.F109V | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV55880798; called by muse, mutect2, varscan2
- GOLGB1 | c.2378T>C p.L793P | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61464931; called by muse, mutect2, varscan2
- GOPC | c.1337G>A p.G446D | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs373622148; called by muse, mutect2, varscan2
- GPC3 | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63662908; called by muse, mutect2, varscan2
- GPLD1 | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57756368; called by muse, mutect2, varscan2
- GPLD1 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.678); catalogued as rs144999503; called by muse, mutect2, varscan2
- GPR158 | c.2168C>T p.A723V | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV66268813; called by muse, mutect2, varscan2
- GPR35 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs527604027, COSV60577039; called by muse, mutect2, varscan2
- GPRASP2 | c.1540T>G p.F514V | Missense Mutation (SNP) | VAF 68/127 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59990976; called by muse, mutect2, varscan2
- GPX7 | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV63652567; called by muse, mutect2, varscan2
- GRB10 | c.953G>A p.G318D (on ENST00000398812; = p.G260D on NM_001001550.3) | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60009753, COSV60017432; called by muse, mutect2, varscan2
- GRID2 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs371291019; called by muse, mutect2, varscan2
- GRM1 | c.1957A>G p.T653A | Missense Mutation (SNP) | VAF 162/648 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.678); catalogued as rs1277903096, COSV51133377; called by muse, mutect2, varscan2
- GRM1 | c.3428C>A p.P1143H | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.72); catalogued as rs745881707, COSV51133540; called by muse, mutect2, varscan2
- GSN | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs745312507; called by muse, mutect2
- GSTA1 | c.239A>G p.N80S | Missense Mutation (SNP) | VAF 126/530 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV58015110; called by muse, mutect2, varscan2
- GTF2E1 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs570890193, COSV52204000; called by muse, mutect2, varscan2
- HAGH | c.618G>T p.E206D | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV68400501; called by muse, mutect2, varscan2
- HAVCR1 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1196575610, COSV59399348; called by muse, mutect2, varscan2
- HCFC1 | c.4211G>A p.G1404D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV60071608; called by muse, mutect2
- HDAC11 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs773395422, COSV55472472; called by muse, mutect2, varscan2
- HECW2 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV99647204; called by muse, mutect2, varscan2
- HELT | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.05); catalogued as rs1380271856, COSV58819864; called by muse, mutect2, varscan2
- HERC2 | c.12002C>T p.T4001M | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372578918; called by muse, mutect2, varscan2
- HERC6 | c.1103C>G p.S368C | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.41); catalogued as COSV52029382; called by muse, mutect2, varscan2
- HIPK4 | c.866A>G p.D289G | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV52520597; called by muse, mutect2
- HIRA | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54274330; called by muse, mutect2, varscan2
- HLA-B | c.19del p.R7Efs*13 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as COSV69520663, COSV69521156; called by mutect2, pindel, varscan2
- HMGA1 | c.172C>T p.R58W (on ENST00000311487 / NM_001319082.2; = p.R47W on NM_002131.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.898); catalogued as COSV58988385; called by muse, mutect2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | catalogued as rs761272507; called by mutect2, varscan2
- HNF4A | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 84/325 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs776824742, COSV57382109; called by muse, mutect2, varscan2
- HNRNPUL1 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV54561801; called by muse, mutect2, varscan2
- HOMEZ | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs888877186, COSV62536853; called by muse, mutect2, varscan2
- HOXA1 | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 76/255 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.047); catalogued as COSV56065949; called by muse, mutect2, varscan2
- HOXA13 | c.1120A>G p.R374G | Missense Mutation (SNP) | VAF 91/376 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56083269; called by muse, mutect2, varscan2
- HOXC9 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as rs767515230, COSV57716646; called by muse, mutect2, varscan2
- HOXD8 | c.329dup p.P111Sfs*31 | Frame Shift Ins (INS) | VAF 20/106 reads (19%) | catalogued as rs770632206; called by mutect2, varscan2
- HPDL | c.901G>T p.G301W | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58344003; called by muse, mutect2, varscan2
- HS1BP3 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58312728; called by muse, mutect2, varscan2
- HS3ST2 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as COSV54460943; called by mutect2, varscan2
- HSPH1 | c.2261C>A p.S754Y | Missense Mutation (SNP) | VAF 75/281 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV104410500, COSV60711104; called by muse, mutect2, varscan2
- HTR1B | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 73/507 reads (14%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as rs750400332, COSV64051170; called by muse, mutect2, varscan2
- HTR1B | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1173501801, COSV64051385; called by muse, mutect2, varscan2
- HTT | c.5777A>G p.D1926G | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs1363469852, COSV61860943; called by muse, mutect2, varscan2
- HUNK | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54227420; called by muse, mutect2
- IARS1 | c.2513G>A p.R838Q | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs370194547; called by muse, mutect2, varscan2
- ICAM4 | c.38del p.L13Wfs*40 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs753968171; called by mutect2, varscan2
- IFNA8 | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 79/310 reads (25%) | catalogued as COSV66504521; called by muse, mutect2, varscan2
- IGBP1P2 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs763860516; called by muse, mutect2, varscan2
- IGF1R | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0.006); catalogued as rs752189789, COSV51281333; called by muse, mutect2, varscan2
- IGFBP5 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV52082449; called by muse, mutect2
- IL12RB2 | c.2360C>T p.T787M | Missense Mutation (SNP) | VAF 95/406 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as rs141507006; called by muse, mutect2, varscan2
- IL34 | c.470A>T p.K157M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55380523; called by muse, mutect2, varscan2
- IL5RA | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56522795; called by muse, mutect2, varscan2
- ILF3 | c.1553G>T p.G518V | Missense Mutation (SNP) | VAF 84/174 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV51556455; called by muse, mutect2, varscan2
- ILF3 | c.2192C>A p.A731D | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV51556472; called by muse, mutect2, varscan2
- IMPA1 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.778); catalogued as COSV56271204; called by muse, mutect2, varscan2
- IMPG1 | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100774808, COSV63113134; called by muse, mutect2, varscan2
- INO80 | c.3877C>T p.R1293* | Nonsense Mutation (SNP) | VAF 36/155 reads (23%) | catalogued as COSV62737569; called by muse, varscan2
- INPP5F | c.631dup p.W211Lfs*3 | Frame Shift Ins (INS) | VAF 32/132 reads (24%) | catalogued as rs768918635; called by mutect2, varscan2
- INPPL1 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1254589846, COSV53354878; called by muse, mutect2, varscan2
- INSYN2A | c.137A>G p.Q46R | Missense Mutation (SNP) | VAF 90/402 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54737324; called by muse, mutect2, varscan2
- IQCE | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs750439401, COSV58077862; called by muse, mutect2, varscan2
- IRAK2 | c.33G>T p.W11C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as COSV99843989; called by muse, mutect2, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs761880048; called by mutect2, varscan2
- ITGAD | c.2891T>C p.I964T | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as rs541431535, COSV54931793; called by muse, mutect2, varscan2
- ITGB3 | c.1678del p.E560Rfs*109 | Frame Shift Del (DEL) | VAF 43/210 reads (20%) | catalogued as rs766268682, COSV101457661; called by mutect2, pindel, varscan2
- ITGB4 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); catalogued as rs146966502, COSV52331798; called by muse, mutect2, varscan2
- JADE1 | c.838G>A p.V280I | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758068684, COSV56905512; called by muse, mutect2, varscan2
- JAG2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV59308279; called by muse, mutect2, varscan2
- JAK3 | c.1978del p.A660Lfs*10 | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | catalogued as COSV71685777; called by mutect2, varscan2
- KBTBD8 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs536406085, COSV55128138; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 23/119 reads (19%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNB1 | c.1594A>G p.M532V | Missense Mutation (SNP) | VAF 109/437 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as COSV65567634; called by muse, mutect2, varscan2
- KCNB2 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.345); catalogued as COSV73049849; called by muse, mutect2, varscan2
- KCNMB3 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV100566754, COSV62895161; called by muse, mutect2, varscan2
- KCNN3 | c.2110C>A p.L704M (on ENST00000618040 / NM_001204087.1; = p.L689M on NM_002249.6) | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55215570; called by muse, mutect2, varscan2
- KCNQ1 | c.1731A>C p.S577= | Splice Region (SNP) | VAF 13/54 reads (24%) | catalogued as COSV50100313, COSV50106045; called by muse, mutect2, varscan2
- KDM3A | c.293A>G p.E98G | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.162); catalogued as COSV57220395; called by muse, mutect2, varscan2
- KIAA0100 | c.3398G>A p.R1133H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs942316532, COSV66492101; called by muse, mutect2, varscan2
- KIAA0753 | c.1964T>G p.L655R | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.563); catalogued as COSV63817255; called by muse, mutect2, varscan2
- KIR2DL4 | c.277C>T p.R93C (on ENST00000396284; = p.R54C on NM_001080770.2) | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs758111394, COSV100610563, COSV60877040, COSV60879620; called by muse, mutect2, varscan2
- KLF4 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 112/415 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867964623, COSV65928854; called by muse, mutect2, varscan2
- KLHDC8A | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV65678666, COSV65679200; called by muse, mutect2, varscan2
- KMT2B | c.7808A>C p.E2603A | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53074605; called by muse, mutect2, varscan2
- KMT2C | c.5870C>T p.T1957M | Missense Mutation (SNP) | VAF 103/508 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs372410972, COSV51431150; called by muse, mutect2, varscan2
- KMT2E | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV57572396; called by muse, varscan2
- KNDC1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as rs775720366, COSV58834074; called by muse, mutect2, varscan2
- KNDC1 | c.4430C>T p.T1477M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs913522508, COSV58835489; called by muse, mutect2
- KPRP | c.619del p.Q207Sfs*4 | Frame Shift Del (DEL) | VAF 63/320 reads (20%) | catalogued as rs1160391112; called by mutect2, pindel, varscan2
- KRT20 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs545785377, COSV51424493; called by muse, mutect2, varscan2
- KRT5 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs776667863, COSV99358027; ClinVar: benign; called by muse, mutect2, varscan2
- L2HGDH | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs779733566, COSV55557170; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LACTB | c.1165G>A p.V389M | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs566925626, COSV56055776; called by muse, mutect2, varscan2
- LAMA2 | c.7067G>A p.R2356H | Missense Mutation (SNP) | VAF 67/280 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs761365739, COSV70342087; called by muse, mutect2, varscan2
- LAMA4 | c.3514G>T p.D1172Y (on ENST00000230538 / NM_001105206.3; = p.D1165Y on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1210063833, COSV57895653, COSV57905490; called by muse, mutect2, varscan2
- LAMA5 | c.3058G>A p.A1020T | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53358205; called by muse, mutect2, varscan2
- LAMB4 | c.3107del p.P1036Lfs*68 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | catalogued as rs903948130, COSV99223933; called by mutect2, varscan2
- LAMC3 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs146887458, COSV63090467; called by muse, mutect2, varscan2
- LAMC3 | c.2369A>G p.D790G | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs147529316; called by muse, mutect2, varscan2
- LANCL2 | c.883T>C p.Y295H | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.519); catalogued as COSV54648434, COSV54648983; called by muse, mutect2
- LAPTM5 | c.624C>A p.C208* | Nonsense Mutation (SNP) | VAF 67/328 reads (20%) | catalogued as COSV53853105; called by muse, mutect2, varscan2
- LCE5A | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.165); catalogued as rs755356448, COSV57500342, COSV57501502; called by muse, varscan2
- LCTL | c.1042T>C p.Y348H | Missense Mutation (SNP) | VAF 69/261 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57179452; called by muse, mutect2, varscan2
- LDHC | c.228G>T p.K76N | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV55004045; called by muse, mutect2, varscan2
- LEMD3 | c.2488C>T p.R830C | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs766583566, COSV57649940; called by muse, mutect2, varscan2
- LGALS9B | c.796G>A p.A266T (on ENST00000423676 / NM_001367292.1; = p.A265T on NM_001042685.2) | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as rs750209193, COSV60864848; called by muse, mutect2, varscan2
- LGR6 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.314); catalogued as rs1328889679, COSV66156093; called by muse, mutect2, varscan2
- LLGL1 | c.1618G>A p.V540I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.984); catalogued as rs1269813675, COSV57497557; called by muse, mutect2, varscan2
- LLGL2 | c.50A>G p.K17R | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as rs1264619960, COSV51348490; called by muse, mutect2, varscan2
- LMAN2 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 95/470 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.102); catalogued as rs376459001; called by muse, mutect2, varscan2
- LNX1 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55788110, COSV99819860; called by muse, mutect2, varscan2
- LRFN3 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55817478; called by muse, mutect2, varscan2
- LRP1 | c.5417C>T p.S1806L | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as rs752838145, COSV99675851; called by muse, mutect2, varscan2
- LRP12 | c.1474A>T p.R492* | Nonsense Mutation (SNP) | VAF 30/147 reads (20%) | catalogued as COSV52627890, COSV52630668; called by muse, mutect2, varscan2
- LRP1B | c.10237A>G p.N3413D | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.751); catalogued as COSV67209122; called by muse, mutect2, varscan2
- LRP1B | c.3763G>A p.V1255I | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV67209126; called by muse, mutect2, varscan2
- LRP2 | c.2716_2718del p.R906del | In Frame Del (DEL) | VAF 24/114 reads (21%) | catalogued as rs758132839; called by pindel, varscan2
- LRRC17 | c.1272dup p.H425Tfs*2 | Frame Shift Ins (INS) | VAF 28/142 reads (20%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC4 | c.554A>T p.E185V | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.332); catalogued as COSV50813748; called by muse, mutect2, varscan2
- LSM14B | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs779339184, COSV53380067; called by muse, mutect2, varscan2
- LTBP1 | c.2789G>A p.R930H (on ENST00000404816 / NM_206943.4; = p.R604H on NM_000627.4) | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.97); catalogued as rs368736095; called by muse, mutect2, varscan2
- LTF | c.1316G>T p.S439I | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.083); catalogued as rs1019548589, COSV51607443; called by muse, mutect2, varscan2
- MACROH2A2 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs375774057; called by muse, mutect2, varscan2
- MAG | c.1522C>T p.R508* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as COSV62699509; called by muse, mutect2, varscan2
- MAGI1 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs779881861, COSV58323115; called by muse, mutect2, varscan2
- MAML3 | c.2723G>T p.G908V | Missense Mutation (SNP) | VAF 21/551 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV72208972; called by muse, mutect2
- MAP10 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs771763362, COSV69363391; called by muse, mutect2, varscan2
- MAP1A | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs750529589, COSV55807975; called by muse, mutect2, varscan2
- MAP1LC3A | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs1336843917, COSV54162073; called by muse, mutect2, varscan2
- MAP3K10 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs750540519, COSV53421779; called by muse, mutect2, varscan2
- MAP3K21 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV64044304; called by muse, mutect2, varscan2
- MAP3K21 | c.2143del p.Q715Rfs*236 | Frame Shift Del (DEL) | VAF 35/133 reads (26%) | catalogued as rs1375324580, COSV64042370; called by mutect2, pindel, varscan2
- MAP6 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs763930019, COSV59075312; called by muse, mutect2
- MAP7 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1374226394, COSV63419037; called by muse, mutect2, varscan2
- MAPK1 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53186038; called by muse, mutect2, varscan2
- MAPKBP1 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52960525; called by muse, mutect2, varscan2
- MCEE | c.49dup p.S17Ffs*50 | Frame Shift Ins (INS) | VAF 30/154 reads (19%) | catalogued as rs1359411004; called by mutect2, pindel
- MCM5 | c.1833-1G>T p.X611_splice | Splice Site (SNP) | VAF 23/75 reads (31%) | catalogued as COSV53345940; called by muse, mutect2, varscan2
- MDC1 | c.5573C>T p.T1858I | Missense Mutation (SNP) | VAF 86/354 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64524291; called by muse, mutect2, varscan2
- MDN1 | c.11393G>T p.R3798L | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV65520668; called by muse, mutect2
- MEF2C | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60929590; called by muse, mutect2, varscan2
- MFAP3L | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64372101; called by muse, mutect2, varscan2
- MFSD2A | c.1052T>G p.L351R (on ENST00000372809 / NM_001136493.3; = p.L338R on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV65685442; called by muse, mutect2, varscan2
- MGAT4C | c.336del p.G113Efs*20 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | catalogued as rs1347429614; called by mutect2, pindel, varscan2
- MICAL3 | c.4214G>A p.R1405Q | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs780451031, COSV71588254; called by muse, mutect2, varscan2
- MINDY2 | c.843G>A p.V281= | Splice Region (SNP) | VAF 36/179 reads (20%) | catalogued as rs1385202670, COSV57506483; called by muse, mutect2, varscan2
- MIPOL1 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 35/135 reads (26%) | catalogued as COSV59383013; called by muse, mutect2, varscan2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 76/264 reads (29%) | catalogued as rs750307488; called by mutect2, varscan2
- MLXIPL | c.1822G>A p.G608S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs782157345, COSV57667903; called by muse, mutect2, varscan2
- MMP24 | c.1661T>C p.V554A | Missense Mutation (SNP) | VAF 67/242 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.737); catalogued as COSV55769601; called by muse, mutect2, varscan2
- MMRN2 | c.2806C>A p.L936M | Missense Mutation (SNP) | VAF 95/397 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV64400670; called by muse, mutect2, varscan2
- MMS22L | c.2799del p.V934Ffs*8 | Frame Shift Del (DEL) | VAF 39/149 reads (26%) | catalogued as rs1562416103; called by mutect2, pindel, varscan2
- MOCS1 | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV51310865; called by muse, mutect2, varscan2
- MPP2 | c.1121G>A p.R374Q (on ENST00000461854 / NM_001278372.2; = p.R350Q on NM_005374.5) | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149942811; called by muse, mutect2, varscan2
- MPPED1 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs769360255, COSV68837885; called by muse, mutect2, varscan2
- MRGPRE | c.191A>G p.D64G | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV67745682; called by muse, mutect2, varscan2
- MROH5 | c.3593G>A p.R1198H | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as rs770448170, COSV61471563; called by muse, mutect2, varscan2
- MST1R | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.959); catalogued as rs1236526255, COSV56567952; called by muse, mutect2, varscan2
- MTCH2 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 43/194 reads (22%) | catalogued as rs1313457585, COSV56767070; called by muse, mutect2, varscan2
- MTDH | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1242588795, COSV60343664; called by muse, mutect2, varscan2
- MTIF2 | c.266del p.K89Rfs*3 | Frame Shift Del (DEL) | VAF 86/445 reads (19%) | catalogued as rs35432898; called by mutect2, pindel, varscan2
- MUC16 | c.37604G>A p.S12535N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.35); catalogued as rs756902469, COSV101200728, COSV67461406; called by muse, mutect2, varscan2
- MUC16 | c.30520A>G p.M10174V | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as COSV101199956; called by muse, mutect2
- MUC6 | c.6697G>A p.V2233M | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs373036328; called by muse, mutect2, varscan2
- MUC6 | c.3044C>T p.T1015M | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs367909154; called by muse, mutect2, varscan2
- MYH10 | c.3283G>A p.A1095T | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.167); catalogued as rs753724964, COSV52599502; called by muse, mutect2, varscan2
- MYH13 | c.4229C>T p.T1410M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs367803525; called by muse, mutect2, varscan2
- MYH4 | c.1823T>C p.V608A | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV55116845; called by muse, mutect2, varscan2
- MYO18B | c.7408C>T p.R2470C | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs370659043; called by muse, mutect2, varscan2
- MYO1H | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs190693741; called by muse, mutect2, varscan2
- MYO5B | c.3823C>T p.R1275* | Nonsense Mutation (SNP) | VAF 29/110 reads (26%) | catalogued as rs760030699, COSV53216850; called by muse, mutect2, varscan2
- MYO9B | c.6049del p.A2017Pfs*36 | Frame Shift Del (DEL) | VAF 33/96 reads (34%) | catalogued as rs1325294870, COSV55727808; called by pindel, varscan2
- MYOM2 | c.2072G>A p.G691E | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754915537, COSV50709087; called by muse, mutect2, varscan2
- MYORG | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 74/292 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.116); catalogued as rs375608013; called by muse, mutect2, varscan2
- MYT1 | c.161G>A p.C54Y | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60504532; called by muse, mutect2, varscan2
- NAA16 | c.1548del p.F516Lfs*3 | Frame Shift Del (DEL) | VAF 24/113 reads (21%) | catalogued as rs749241638; called by mutect2, pindel
- NALCN | c.4381C>T p.L1461F | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51931161; called by muse, mutect2, varscan2
- NCKAP1L | c.2611G>C p.V871L | Missense Mutation (SNP) | VAF 81/322 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53205940; called by muse, mutect2, varscan2
- NCOA2 | c.3361G>A p.D1121N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as COSV51219046, COSV99144703; called by muse, mutect2, varscan2
- NCOR1 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs1251718838, COSV51971754; called by muse, mutect2, varscan2
- NCOR2 | c.6998C>T p.A2333V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV62296852, COSV62306517; called by muse, mutect2, varscan2
- NCOR2 | c.3904dup p.H1302Pfs*2 | Frame Shift Ins (INS) | VAF 20/112 reads (18%) | catalogued as rs768164546; called by mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 44/193 reads (23%) | catalogued as rs747914168; called by mutect2, varscan2
- NDUFV1 | c.1093A>G p.K365E | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.05); catalogued as COSV59595194; called by muse, mutect2, varscan2
- NEIL2 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs867942520, COSV52706662; called by muse, mutect2, varscan2
- NEK10 | c.1911+1G>A p.X637_splice | Splice Site (SNP) | VAF 29/134 reads (22%) | catalogued as COSV100411185, COSV58282582; called by muse, mutect2, varscan2
- NEUROD6 | c.248del p.K83Rfs*35 | Frame Shift Del (DEL) | VAF 92/388 reads (24%) | catalogued as rs752284115; called by mutect2, varscan2
- NHLRC1 | c.612del p.F204Lfs*28 | Frame Shift Del (DEL) | VAF 30/108 reads (28%) | catalogued as rs1171412241, CD054388; called by mutect2, pindel, varscan2
- NKD1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs757531250, COSV51689427; called by muse, mutect2, varscan2
- NKTR | c.1847del p.P616Lfs*21 | Frame Shift Del (DEL) | VAF 78/328 reads (24%) | catalogued as rs763440516; called by mutect2, varscan2
- NLE1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs745418741, COSV62604060; called by muse, mutect2, varscan2
- NLRC4 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs572809664, COSV61592308; called by muse, mutect2, varscan2
- NOB1 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs746189885, COSV52061373; called by muse, mutect2, varscan2
- NOBOX | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.585); catalogued as rs762139523, COSV56193767, COSV56193847; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOD1 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.671); catalogued as rs367963834, COSV56112139; called by muse, mutect2, varscan2
- NOL11 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs202096165, COSV53523071; called by muse, mutect2
- NOL6 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53041055; called by muse, mutect2, varscan2
- NOL8 | c.2444A>G p.Q815R | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as COSV62635090; called by muse, mutect2, varscan2
- NOTCH3 | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.903); catalogued as rs115836330, CM150661, COSV54632917; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NOVA1 | c.1504A>G p.N502D | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV57475589; called by muse, mutect2, varscan2
- NPBWR1 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs749431371, COSV100488244, COSV58696009; called by muse, mutect2, varscan2
- NPBWR2 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as rs370207328; called by muse, mutect2, varscan2
- NPC1 | c.3821G>A p.R1274Q | Missense Mutation (SNP) | VAF 63/292 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs151305963; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPIPB3 | c.431C>A p.P144H | Missense Mutation (SNP) | VAF 23/286 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as rs765486033, COSV101341636; called by muse, mutect2, varscan2
- NR3C2 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as COSV60989052; called by muse, mutect2, varscan2
- NR5A1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV65294844; called by muse, mutect2, varscan2
- NR6A1 | c.1111C>T p.R371W (on ENST00000487099 / NM_033334.4; = p.R366W on NM_001489.5) | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs368063288; called by muse, mutect2, varscan2
- NRGN | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV52518330; called by muse, mutect2, varscan2
- NUCB1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54385066; called by muse, mutect2, varscan2
- NUDT21 | c.98T>G p.L33R | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV55859773; called by muse, varscan2
- NUP62 | c.845C>G p.T282S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs149572563, COSV61310774; called by muse, mutect2, varscan2
- NUTM1 | c.812C>T p.T271I | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV61546806; called by muse, mutect2, varscan2
- NXPE1 | c.1200dup p.H401Tfs*2 (on ENST00000424269; = p.H259Tfs*2 on NM_152315.5) | Frame Shift Ins (INS) | VAF 34/187 reads (18%) | catalogued as rs768846260; called by mutect2, pindel, varscan2
- OBSCN | c.10190G>A p.R3397H | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs559670799, COSV52765980; called by muse, mutect2, varscan2
- OCA2 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs372899234, COSV100667606; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OLFM1 | c.804T>A p.Y268* (on ENST00000371793 / NM_001282611.2; = p.Y250* on NM_014279.5) | Nonsense Mutation (SNP) | VAF 50/172 reads (29%) | catalogued as COSV53277909; called by muse, mutect2, varscan2
- OR10Q1 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV57470257; called by muse, varscan2
- OR10Q1 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs770134300, COSV57470266; called by muse, mutect2, varscan2
- OR11L1 | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as rs376918027; called by muse, mutect2, varscan2
- OR13C4 | c.102G>A p.M34I | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV52926362; called by muse, mutect2, varscan2
- OR14J1 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 94/360 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs947209841, COSV65845628; called by muse, mutect2, varscan2
- OR1Q1 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs560739249, COSV52917800, COSV52918919; called by muse, mutect2, varscan2
- OR2L8 | c.718T>C p.C240R | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61726540; called by muse, mutect2
- OR2T2 | c.142C>G p.L48V | Missense Mutation (SNP) | VAF 34/291 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV61617966; called by muse, mutect2, varscan2
- OR2T8 | c.235dup p.M79Nfs*4 | Frame Shift Ins (INS) | VAF 25/204 reads (12%) | catalogued as rs748922390; called by mutect2, pindel, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 49/308 reads (16%) | catalogued as rs748398423; called by mutect2, pindel, varscan2
- OR4Q3 | c.520C>A p.Q174K | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV59178352; called by muse, mutect2
- OR4X1 | c.776C>A p.P259H | Missense Mutation (SNP) | VAF 62/335 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60722701; called by muse, mutect2, varscan2
- OR5K2 | c.770del p.F257Sfs*24 | Frame Shift Del (DEL) | VAF 22/123 reads (18%) | catalogued as rs747087385, COSV71143530; called by mutect2, pindel, varscan2
- OR5R1 | c.845T>C p.I282T | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV56572119; called by muse, mutect2, varscan2
- OR6C1 | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.12); catalogued as COSV65573242; called by muse, mutect2, varscan2
- OR6C76 | c.699del p.A234Pfs*9 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | catalogued as rs771987454; called by mutect2, pindel, varscan2
- OSBP2 | c.2443G>A p.V815I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.324); catalogued as rs568444280, COSV60241959; called by muse, mutect2, varscan2
- OTOGL | c.6016del p.C2006Vfs*21 (on ENST00000547103; = p.C1997Vfs*21 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | catalogued as COSV100087754; called by mutect2, pindel
- OTUD7B | c.2304del p.Y769Tfs*59 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as COSV64917254; called by mutect2, pindel, varscan2
- OXTR | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV57479038; called by muse, mutect2, varscan2
- P2RX2 | c.107T>C p.V36A (on ENST00000343948 / NM_170683.4; = p.X35_splice on NM_012226.5) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.998); catalogued as COSV57678704; called by muse, mutect2, varscan2
- P2RX4 | c.723_724del p.H241Qfs*44 | Frame Shift Del (DEL) | VAF 46/251 reads (18%) | catalogued as rs1222387860; called by pindel, varscan2
- P2RX6 | c.706C>A p.P236T | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60383332; called by muse, mutect2, varscan2
- PADI3 | c.1374del p.V459Wfs*17 | Frame Shift Del (DEL) | VAF 37/169 reads (22%) | catalogued as rs747531633; called by mutect2, pindel, varscan2
- PAMR1 | c.302del p.G101Vfs*8 | Frame Shift Del (DEL) | VAF 89/531 reads (17%) | catalogued as rs751755759; called by mutect2, pindel, varscan2
- PANK1 | c.1523C>G p.S508C (on ENST00000307534 / NM_148977.2; = p.S224C on NM_138316.4) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV56807738; called by muse, mutect2, varscan2
- PAQR6 | c.727G>A p.E243K (on ENST00000292291 / NM_001272108.2; = p.E137K on NM_024897.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52744939, COSV99430938; called by muse, mutect2, varscan2
- PARP11 | c.146A>G p.Q49R | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV57394656; called by muse, mutect2, varscan2
- PAXX | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as rs748192394, COSV65406519; called by muse, mutect2, varscan2
- PBX2 | c.130del p.V44Sfs*17 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs747720400, COSV66708728; called by mutect2, pindel
- PCDH1 | c.2712G>T p.K904N | Missense Mutation (SNP) | VAF 85/318 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); catalogued as COSV54613413; called by muse, mutect2, varscan2
- PCDH18 | c.3145T>C p.Y1049H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV61267836; called by muse, mutect2, varscan2
- PCDH19 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV55257171; called by muse, mutect2, varscan2
- PCDHB10 | c.1617del p.A540Rfs*2 | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | catalogued as rs781944538, COSV53378385; called by mutect2, pindel, varscan2
- PCDHB16 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 74/306 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.517); catalogued as COSV53361271; called by muse, mutect2, varscan2
- PCDHB8 | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 88/1124 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.437); catalogued as rs781858766, COSV50763047; called by muse, mutect2
- PCDHB9 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 14/469 reads (3%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.033); catalogued as rs782419413; called by muse, mutect2
- PCDHGA10 | c.65T>A p.L22H | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV53933293; called by muse, mutect2, varscan2
- PCDHGA10 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.444); catalogued as rs777981621, COSV53933301; called by muse, mutect2, varscan2
- PCF11 | c.1435C>T p.R479* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as COSV53527008; called by muse, mutect2, varscan2
- PCID2 | c.818del p.K273Sfs*4 | Frame Shift Del (DEL) | VAF 59/239 reads (25%) | catalogued as rs760522684; called by mutect2, pindel, varscan2
- PCLO | c.7587A>G p.I2529M | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV61629803; called by muse, mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCP4 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV60787016; called by muse, mutect2, varscan2
- PDE2A | c.1345G>A p.V449M | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV57805546; called by muse, mutect2, varscan2
- PDE6B | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV55325707; called by muse, mutect2, varscan2
- PDE9A | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as rs771947665, COSV52325166; called by muse, mutect2, varscan2
- PDZD2 | c.145A>G p.N49D | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56856592; called by muse, mutect2, varscan2
- PDZD2 | c.1609C>T p.R537* | Nonsense Mutation (SNP) | VAF 20/95 reads (21%) | catalogued as rs766389561, COSV56856603; called by muse, mutect2, varscan2
- PDZD3 | c.664C>T p.R222W (on ENST00000531114; = p.R156W on NM_024791.4) | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140060249; called by muse, mutect2, varscan2
- PEX2 | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63813437; called by muse, mutect2, varscan2
- PEX5L | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 90/423 reads (21%) | catalogued as COSV55844200; called by muse, mutect2, varscan2
- PHACTR2 | c.685dup p.T229Nfs*5 | Frame Shift Ins (INS) | VAF 42/204 reads (21%) | catalogued as rs746858891; called by mutect2, varscan2
- PHLDB1 | c.1660C>A p.Q554K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.217); catalogued as COSV61877889; called by muse, mutect2
- PHLPP1 | c.4496C>T p.P1499L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs201439333, COSV53021243; called by muse, mutect2, varscan2
- PHYHIPL | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.07); catalogued as rs776129253, COSV65848467; called by muse, mutect2, varscan2
- PIH1D2 | c.389A>G p.Q130R | Missense Mutation (SNP) | VAF 92/419 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54775315; called by muse, mutect2, varscan2
- PKD1L2 | c.2389G>A p.A797T | Missense Mutation (SNP) | VAF 51/258 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs370023428; called by muse, mutect2, varscan2
- PKLR | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 98/373 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.487); catalogued as COSV61361009; called by muse, mutect2, varscan2
- PKNOX1 | c.697A>T p.T233S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.294); catalogued as COSV52335539; called by muse, mutect2, varscan2
- PLAT | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747692088, COSV51528440; called by muse, mutect2, varscan2
- PLBD2 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199763130, COSV55106524; called by muse, mutect2, varscan2
- PLCB1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs868772684, COSV62047584; called by muse, mutect2, varscan2
- PLCD3 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs772588454, COSV59560046; called by muse, mutect2, varscan2
- PLEC | c.5030A>C p.E1677A (on ENST00000322810 / NM_201380.4; = p.E1567A on NM_000445.5) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs1206278709, COSV100514183; called by muse, varscan2
- PLEK2 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 69/285 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377373834; called by muse, mutect2, varscan2
- PLEKHA4 | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as rs369201187; called by muse, mutect2, varscan2
- PLK2 | c.1004del p.L335Cfs*68 | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | catalogued as rs772701630; called by mutect2, varscan2
- PLXNA3 | c.1978C>T p.R660C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1490761563, COSV63753863; called by muse, mutect2, varscan2
- PNLDC1 | c.725T>C p.F242S | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51705103; called by muse, mutect2
- PNMA8B | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV66536404; called by muse, mutect2, varscan2
- PNMT | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV54092867; called by muse, mutect2, varscan2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POLE | c.207C>T p.T69= | Splice Region (SNP) | VAF 31/134 reads (23%) | catalogued as rs146986360, COSV57678711; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- PPP1R3C | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs377306002; called by muse, mutect2, varscan2
- PPP1R3F | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs782241292, COSV50018136; called by muse, mutect2, varscan2
- PRDX3 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs370154302; called by muse, mutect2, varscan2
- PREX1 | c.2245C>T p.Q749* | Nonsense Mutation (SNP) | VAF 52/234 reads (22%) | catalogued as COSV64250875; called by muse, mutect2, varscan2
- PRKACB | c.340A>G p.N114D | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.074); catalogued as COSV65759409; called by muse, mutect2, varscan2
- PRKN | c.892A>T p.I298F | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs1273010274, CM081387, COSV58219677; called by muse, mutect2, varscan2
- PRPF40B | c.99del p.M34Cfs*29 (on ENST00000380281; = p.M28Cfs*29 on NM_012272.3) | Frame Shift Del (DEL) | VAF 93/374 reads (25%) | catalogued as COSV56058435; called by mutect2, pindel, varscan2
- PSEN2 | c.566+2T>C p.X189_splice | Splice Site (SNP) | VAF 39/126 reads (31%) | catalogued as COSV60915840; called by muse, mutect2, varscan2
- PTPRG | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs1437859583, COSV55638066; called by muse, mutect2, varscan2
- PTPRM | c.3680G>T p.R1227L | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100156385, COSV59855280; called by muse, mutect2, varscan2
- PTPRN | c.1442T>C p.L481P | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55347387; called by muse, mutect2, varscan2
- PTPRT | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs200302453; called by muse, mutect2, varscan2
- PTRHD1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs1238843879, COSV53230088; called by muse, mutect2, varscan2
- PWWP2A | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs754247679, COSV61045973; called by muse, mutect2, varscan2
- PYHIN1 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV63722209; called by muse, mutect2, varscan2
- PYHIN1 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 29/116 reads (25%) | catalogued as rs144716673; called by muse, mutect2, varscan2
- PZP | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs777042504, COSV54358800; called by muse, mutect2, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 32/145 reads (22%) | catalogued as rs755727862; called by mutect2, varscan2
- RAB11FIP1 | c.2645C>T p.A882V | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.767); catalogued as rs1369820329, COSV54759457; called by muse, mutect2, varscan2
- RAB40C | c.272T>G p.L91R | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV50193344; called by muse, mutect2, varscan2
- RABGAP1L | c.2234A>G p.Q745R | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.216); catalogued as COSV52290714; called by muse, mutect2, varscan2
- RAD50 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs876658808, COSV54748818, COSV54750515; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RANBP3 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1218257373, COSV50381202; called by muse, mutect2, varscan2
- RARA | c.89del p.P30Lfs*12 | Frame Shift Del (DEL) | VAF 15/107 reads (14%) | catalogued as COSV99565582; called by mutect2, pindel, varscan2
- RASA1 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV57194722, COSV99171476; called by muse, mutect2, varscan2
- RASGRF2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54128082; called by muse, mutect2
- RASL11A | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV54080056; called by muse, mutect2, varscan2
- RASL12 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1216496113; called by muse, mutect2
- RBM14 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as rs1281990980, COSV59558672; called by muse, mutect2, varscan2
- RBP3 | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as rs782217999; called by muse, mutect2, varscan2
- RELN | c.7432G>A p.G2478R | Missense Mutation (SNP) | VAF 54/256 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58998103; called by muse, mutect2, varscan2
- RFX7 | c.2771G>T p.R924M (on ENST00000559447 / NM_001368074.1; = p.R1021M on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57962600; called by muse, mutect2, varscan2
- RHAG | c.294G>T p.Q98H | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV57704014, COSV57704543; called by muse, mutect2, varscan2
- RHOQ | c.577del p.R193Efs*2 | Frame Shift Del (DEL) | VAF 21/134 reads (16%) | catalogued as rs1368074831, COSV53191234; called by mutect2, varscan2
- RIC8A | c.1523C>T p.T508M (on ENST00000526104 / NM_001286134.1; = p.T514M on NM_021932.5) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs776558817, COSV57342551; called by muse, varscan2
- RIPOR2 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773866451, COSV52420249; called by muse, mutect2, varscan2
- RMDN2 | c.975_976del p.K325Nfs*23 (on ENST00000354545 / NM_001322212.2; = p.K503Nfs*23 on NM_144713.5) | Frame Shift Del (DEL) | VAF 20/123 reads (16%) | catalogued as rs770517879; called by mutect2, pindel, varscan2
- RNF123 | c.1961G>A p.R654H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs772515271, COSV59686495; called by mutect2, varscan2
- RNF19B | c.2065del p.R689Afs*23 | Frame Shift Del (DEL) | VAF 26/144 reads (18%) | catalogued as rs1203386837; called by mutect2, pindel, varscan2
- RNF217 | c.387del p.G130Afs*66 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs757325037; called by mutect2, pindel, varscan2
- RNF25 | c.337A>G p.M113V | Missense Mutation (SNP) | VAF 61/283 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs1455927430, COSV55306969; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 82/258 reads (32%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNLS | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs747724619, COSV59292792; called by muse, mutect2, varscan2
- RNPEPL1 | c.2138G>A p.S713N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.003); catalogued as COSV54372414; called by muse, mutect2, varscan2
- ROBO2 | c.1276A>G p.N426D | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59907867; called by muse, mutect2, varscan2
- ROBO3 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs1243155901, COSV67300618; called by muse, mutect2
- RORC | c.1148G>A p.G383D | Missense Mutation (SNP) | VAF 141/669 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59092660; called by muse, mutect2, varscan2
- RPL22 | c.43_44del p.K15Efs*9 | Frame Shift Del (DEL) | VAF 17/97 reads (18%) | catalogued as rs759765382; called by pindel, varscan2*
- RSPH6A | c.740C>T p.T247M | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as rs749446018, COSV55570000; called by muse, mutect2, varscan2
- RSPO4 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370909673; called by muse, mutect2
- RTN4IP1 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV64805283; called by muse, mutect2, varscan2
- RUFY3 | c.1195G>T p.D399Y | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV56913056; called by muse, mutect2, varscan2
- RUSC2 | c.3342-1G>T p.X1114_splice | Splice Site (SNP) | VAF 43/145 reads (30%) | catalogued as COSV63428457; called by muse, mutect2, varscan2
- RYR1 | c.5734G>T p.E1912* | Nonsense Mutation (SNP) | VAF 23/117 reads (20%) | catalogued as COSV62095232; called by muse, mutect2, varscan2
- RYR2 | c.12580G>A p.E4194K | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs762038111, COSV63680501, COSV63708467; called by muse, mutect2, varscan2
- RYR3 | c.8093G>A p.R2698Q (on ENST00000389232; = p.R2699Q on NM_001036.6) | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.242); catalogued as rs1352697289, COSV66785694; called by muse, mutect2, varscan2
- S100A14 | c.161T>C p.L54P | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100275245; called by muse, mutect2, varscan2
- S100A7A | c.92G>T p.S31I | Missense Mutation (SNP) | VAF 54/256 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV61330424; called by muse, mutect2, varscan2
- S1PR1 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.106); catalogued as rs1557708024, COSV59513012; called by muse, mutect2, varscan2
- SALL3 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as rs758917162, COSV101609999; called by muse, varscan2
- SCAF11 | c.1390T>C p.Y464H | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1280904597, COSV65476200; called by muse, mutect2, varscan2
- SCARA3 | c.372G>T p.Q124H | Missense Mutation (SNP) | VAF 77/359 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.41); catalogued as COSV57269976; called by muse, mutect2, varscan2
- SCARB1 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.718); catalogued as rs759465275, COSV55546704; called by muse, mutect2, varscan2
- SCG3 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.975); catalogued as COSV51056791; called by muse, mutect2, varscan2
- SCLT1 | c.1269dup p.A424Sfs*12 | Frame Shift Ins (INS) | VAF 24/100 reads (24%) | catalogued as rs781735051; called by mutect2, varscan2
- SCN10A | c.4744C>T p.R1582C | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs569261408, COSV71861065; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN5A | c.5425A>G p.I1809V (on ENST00000333535 / NM_198056.3; = p.I1808V on NM_000335.5) | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); catalogued as rs1299165746, COSV61121806; called by muse, mutect2, varscan2
- SCUBE1 | c.89-2A>G p.X30_splice | Splice Site (SNP) | VAF 17/84 reads (20%) | catalogued as COSV51810737; called by muse, mutect2, varscan2
- SDCBP2 | c.347G>A p.R116H (on ENST00000339987 / NM_001199784.1; = p.R31H on NM_015685.5) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV60588974; called by muse, mutect2, varscan2
- SDK1 | c.1792A>G p.T598A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as COSV67365547; called by muse, mutect2
- SEC23B | c.1123A>T p.M375L | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV52719829; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 42/99 reads (42%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA5B | c.2060G>A p.R687H | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1238052538, COSV52096040; called by muse, mutect2, varscan2
- SEMA6C | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59002279; called by muse, mutect2, varscan2
- SET | c.539C>T p.T180M (on ENST00000372692 / NM_001374326.1; = p.T167M on NM_003011.4) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.473); catalogued as rs1311290908, COSV59002287; called by muse, mutect2, varscan2
- SGO2 | c.2278G>T p.D760Y | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs761916820, COSV63414945; called by muse, mutect2, varscan2
- SH2D3C | c.1265-1G>A p.X422_splice (on ENST00000314830 / NM_170600.3; = p.X265_splice on NM_005489.4) | Splice Site (SNP) | VAF 22/79 reads (28%) | catalogued as rs746092833, COSV59121832; called by muse, mutect2, varscan2
- SH3PXD2B | c.670_672del p.E224del | In Frame Del (DEL) | VAF 16/94 reads (17%) | catalogued as rs762010216; called by pindel, varscan2
- SHC2 | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.838); catalogued as COSV52745418; called by muse, mutect2, varscan2
- SHTN1 | c.1607del p.P536Qfs*45 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | catalogued as COSV53382008; called by mutect2, pindel
- SI | c.887del p.L296* | Frame Shift Del (DEL) | VAF 17/107 reads (16%) | catalogued as rs769103567, COSV52291108; called by mutect2, pindel, varscan2
- SIPA1L1 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs148152996; called by muse, mutect2, varscan2
- SLC16A13 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 87/393 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759963974, COSV57274111; called by muse, mutect2, varscan2
- SLC16A5 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758644893, COSV61675699; called by muse, mutect2, varscan2
- SLC25A2 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781985961, COSV53403577; called by muse, mutect2
- SLC27A2 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.21); catalogued as rs767050184, COSV51058594; called by muse, mutect2, varscan2
- SLC27A5 | c.615C>A p.N205K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54019105; called by muse, mutect2, varscan2
- SLC27A6 | c.1255+2T>C p.X419_splice | Splice Site (SNP) | VAF 12/62 reads (19%) | catalogued as rs775925497, COSV52482340; called by muse, varscan2
- SLC47A1 | c.717dup p.L240Tfs*39 | Frame Shift Ins (INS) | VAF 39/195 reads (20%) | catalogued as rs762001651; called by mutect2, pindel, varscan2
- SLC4A1 | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs745505408, COSV52259596; called by muse, mutect2, varscan2
- SLC4A2 | c.2756G>A p.R919H | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172824484, COSV52539828; called by muse, mutect2, varscan2
- SLC4A3 | c.2347C>T p.R783* | Nonsense Mutation (SNP) | VAF 25/137 reads (18%) | catalogued as rs150010736; called by muse, mutect2, varscan2
- SLC5A10 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.713); catalogued as rs1244151063, COSV58757447; called by muse, mutect2, varscan2
- SMARCA2 | c.3314G>A p.R1105H | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM122564, CM1310760, COSV61806697; called by muse, mutect2, varscan2
- SMG1 | c.8584C>T p.R2862W | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs540679816, COSV67170815; called by muse, mutect2, varscan2
- SMG8 | c.1006G>A p.V336M | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56284915; called by muse, mutect2, varscan2
- SMO | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs142599757, COSV50825607; called by muse, mutect2, varscan2
- SMO | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 31/111 reads (28%) | catalogued as rs1405848770, COSV50827516; called by muse, mutect2, varscan2
- SMTN | c.714del p.S239Afs*118 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs747405143; called by mutect2, varscan2
- SMYD5 | c.1103T>C p.L368P | Missense Mutation (SNP) | VAF 132/489 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV50264660; called by muse, mutect2, varscan2
- SNAPC4 | c.1358A>G p.K453R | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV53732560; called by muse, mutect2, varscan2
- SND1 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61235157; called by muse, mutect2, varscan2
- SNTG2 | c.1077G>A p.K359= | Splice Region (SNP) | VAF 13/77 reads (17%) | catalogued as rs538342778, COSV57978592; called by muse, mutect2, varscan2
- SNX1 | c.731+2T>C p.X244_splice | Splice Site (SNP) | VAF 17/53 reads (32%) | catalogued as COSV56038029; called by muse, mutect2, varscan2
- SORT1 | c.2265T>G p.N755K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV56665738; called by muse, mutect2, varscan2
- SPAG16 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59088034; called by muse, mutect2, varscan2
- SPAG9 | c.2696C>T p.A899V (on ENST00000262013 / NM_001130528.3; = p.A885V on NM_003971.6) | Missense Mutation (SNP) | VAF 80/308 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as rs768131495, COSV56231993; called by muse, mutect2, varscan2
- SPAG9 | c.1645del p.R549Gfs*28 (on ENST00000262013 / NM_001130528.3; = p.R535Gfs*28 on NM_003971.6) | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | catalogued as rs371303534; called by mutect2, varscan2
- SPATA20 | c.974A>G p.Q325R (on ENST00000356488 / NM_001258372.1; = p.Q341R on NM_022827.4) | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV50066386; called by muse, mutect2, varscan2
- SPINDOC | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV53692401; called by muse, mutect2, varscan2
- SPINT2 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs781030322, COSV56647713; called by muse, mutect2, varscan2
- SPOP | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as rs866898949, COSV61653713; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 46/246 reads (19%) | catalogued as rs748467821; called by mutect2, varscan2
- SRSF6 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54827464, COSV54828681; called by muse, mutect2, varscan2
- SSBP1 | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV54681222; called by muse, mutect2, varscan2
- SSTR2 | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.029); catalogued as rs752083493, COSV59535109; called by muse, mutect2, varscan2
- ST13 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as rs371323187; called by muse, mutect2, varscan2
- STARD13 | c.2642C>T p.S881L (on ENST00000336934 / NM_001243476.3; = p.S763L on NM_052851.3) | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55229729; called by muse, varscan2
- STAU1 | c.941C>T p.P314L (on ENST00000371856 / NM_001319135.1; = p.P233L on NM_004602.3) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs200245504, COSV100574507, COSV61459993; called by muse, mutect2, varscan2
- STMN4 | c.329C>T p.A110V (on ENST00000265770 / NM_001283054.2; = p.A137V on NM_030795.4) | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as rs755190482, COSV56108653; called by muse, mutect2, varscan2
- STOML2 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59715756; called by muse, mutect2, varscan2
- STXBP5 | c.1705G>A p.V569M | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.157); catalogued as rs959329086, COSV51651130; called by muse, mutect2, varscan2
- SUDS3 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1185298509, COSV64348796; called by muse, mutect2
- SUPT5H | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 99/429 reads (23%) | catalogued as COSV63239219; called by muse, mutect2, varscan2
- SVEP1 | c.2485del p.M829Wfs*20 | Frame Shift Del (DEL) | VAF 95/412 reads (23%) | catalogued as rs1468278719; called by mutect2, pindel, varscan2
- SWAP70 | c.632T>C p.V211A | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV59663477; called by muse, mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | catalogued as rs570102997; called by mutect2, varscan2
- SYCP2 | c.526del p.M176* | Frame Shift Del (DEL) | VAF 26/112 reads (23%) | catalogued as rs1346657016; called by mutect2, varscan2
- SYCP2L | c.551A>T p.E184V | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51652447; called by muse, mutect2, varscan2
- SYNE2 | c.17635G>A p.V5879I | Missense Mutation (SNP) | VAF 78/342 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs555731479, COSV59948000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF15 | c.1468C>T p.R490* (on ENST00000605844 / NM_139215.3; = p.R487* on NM_003487.4) | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as rs1245865038; called by muse, mutect2, varscan2
- TAOK3 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.374); catalogued as rs373223808; called by muse, mutect2, varscan2
- TAS2R9 | c.560del p.V187Gfs*9 | Frame Shift Del (DEL) | VAF 24/122 reads (20%) | catalogued as CM087521; called by mutect2, varscan2
- TASOR2 | c.6836C>A p.A2279E | Missense Mutation (SNP) | VAF 130/495 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV60167042; called by muse, mutect2, varscan2
- TBC1D14 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.17); catalogued as rs371738551; called by muse, mutect2, varscan2
- TBCD | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs1293440048, COSV62798793; called by muse, mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs748021112; called by mutect2, varscan2
- TCHHL1 | c.2152A>C p.N718H | Missense Mutation (SNP) | VAF 70/275 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV64285538; called by muse, mutect2, varscan2
- TDRD1 | c.2813T>C p.V938A | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV52589894; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 75/402 reads (19%) | catalogued as rs763321097; called by mutect2, varscan2
- TEP1 | c.5566del p.V1856Lfs*45 | Frame Shift Del (DEL) | VAF 34/152 reads (22%) | catalogued as rs746695887; called by mutect2, varscan2
- TFAP4 | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 15/69 reads (22%) | catalogued as COSV52597397; called by muse, mutect2, varscan2
- THBS2 | c.2242G>A p.G748S | Missense Mutation (SNP) | VAF 56/245 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as rs201813061, COSV64678157; called by muse, mutect2, varscan2
- THSD7A | c.1987C>T p.R663* | Nonsense Mutation (SNP) | VAF 35/132 reads (27%) | catalogued as rs745415841, COSV70263921; called by muse, mutect2, varscan2
- TIMELESS | c.2988G>T p.Q996H | Missense Mutation (SNP) | VAF 54/241 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV57510821; called by muse, mutect2, varscan2
562 further variants in this file (260 protein-altering or splice-affecting, 277 silent, 25 other) are not listed here.
